Gene-level copy-number profile of tumor specimen ALCH-B1RQ-TTP1-A from ALCHEMIST case ALCH-B1RQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.9 years (26,248 days).
Specimen ALCH-B1RQ-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3f9ea2dc-d7c4-4b9e-a4cf-08c4c9e7637b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1RQ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/d7379ebe-f06b-4738-91e1-149c41444134

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 1,472; copy number 2: 56,234; copy number 3: 661; copy number 4: 3; copy number 5: 5; copy number 6: 2; copy number 9: 3.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,905,487–143,934,776, 2 genes (within-gene range 0–2): AC246680.1, RPL22P5.
- chr2:71,002,531–71,064,743, 4 genes (within-gene range 0–2): AC007881.2, OR7E91P, OR7E46P, OR7E62P.
- chr3:125,703,349–125,704,312, 1 gene: OR7E130P.
- chr5:135,802,985–135,803,075, 1 gene: MIR5692C1.
- chr6:42,960,754–42,979,181, 2 genes: GNMT, PEX6.
- chr7:7,066,964–7,067,045, 1 gene: MIR3683.
- chr17:18,968,789–19,004,764, 2 genes (within-gene range 0–1): FAM83G, AC090286.4.
- chr19:41,449,520–41,521,989, 3 genes: PCAT19, AC243960.2, PLEKHA3P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:150,584–167,043, 3 genes, copy number 9: AC131281.2, WBP1LP3, OR4F21.
- chr19:55,428,740–55,462,343, 2 genes, copy number 6: SHISA7, ISOC2.
- chr22:15,282,557–15,350,043, 5 genes, copy number 5: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2.

Autosomal genes at a single copy (total copy number 1): 1,472. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
